Somatic mutation profile of tumor specimen TCGA-VQ-A91A-01A (aliquot TCGA-VQ-A91A-01A-11D-A410-08) from TCGA case TCGA-VQ-A91A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 67.5 years (24,670 days).
Specimen TCGA-VQ-A91A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dccdc86-9674-4501-8e78-d2269050de6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91A-10A (Blood Derived Normal), aliquot TCGA-VQ-A91A-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70d807a0-ce1a-42bb-9d46-b8d7911f4ccc

The open-access MAF lists 134 somatic variants for this specimen: 107 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 22, Frame Shift Ins 5, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 2, Intron 2, RNA 2, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15641G>A p.R5214H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3635T>G p.L1212R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99652467; called by muse, mutect2, varscan2
- AHNAK2 | c.2043G>T p.K681N | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100317625; called by muse, mutect2, varscan2
- ALOX15B | c.552T>G p.F184L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101205622; called by muse, mutect2, varscan2
- ANKRD30A | c.3599C>A p.P1200H (on ENST00000611781; = p.P1144H on NM_052997.2) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64614472; called by muse, mutect2, varscan2
- AP5M1 | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV99841222; called by muse, varscan2
- ARHGEF26 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs1197711696, COSV62852255; called by muse, mutect2, varscan2
- ASTN1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as COSV99921822; called by muse, mutect2, varscan2
- ATP4A | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs767066130, COSV52871066; called by muse, mutect2, varscan2
- BMP5 | c.977G>C p.R326P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV100895985, COSV63707374; called by muse, mutect2, varscan2
- BTAF1 | c.3922G>C p.D1308H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795385; called by muse, mutect2, varscan2
- C3 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1421843172, COSV55577235; called by muse, mutect2, varscan2
- C5AR1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs750171124, COSV100754027, COSV100754075; called by muse, mutect2, varscan2
- CACNA2D4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1446549662, COSV54960579; called by muse, mutect2
- CDS2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs144822618; called by muse, mutect2, varscan2
- CHRM2 | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100281350; called by muse, mutect2, varscan2
- CMYA5 | c.7721T>A p.I2574N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as COSV101484071; called by muse, mutect2, varscan2
- COL4A1 | c.2266del p.E756Rfs*46 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | catalogued as COSV65430452; called by mutect2, pindel, varscan2
- COL6A3 | c.3653C>T p.P1218L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs75071027, COSV99798466; called by muse, mutect2, varscan2
- CPNE8 | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100504426; called by muse, mutect2, varscan2
- CSTF1 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410199; called by muse, mutect2
- CWC27 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV66887027; called by muse, mutect2, varscan2
- DCC | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780738407, COSV59095079, COSV59142839; called by muse, mutect2, varscan2
- DGKH | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99818872; called by muse, mutect2, varscan2
- DIPK1B | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs536659122, COSV63038251; called by muse, mutect2
- DNAH17 | c.9441C>A p.N3147K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV101102412; called by muse, mutect2, varscan2
- DNAH17 | c.7669A>G p.T2557A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as COSV101102414; called by muse, mutect2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUT | c.556G>A p.A186T (on ENST00000331200 / NM_001025248.2; = p.A98T on NM_001948.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100485254; called by muse, mutect2, varscan2
- DYNC1LI1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99818175; called by muse, mutect2, varscan2
- EEF2 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as rs749851802, COSV58578690; called by muse, mutect2, varscan2
- EMC1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs750358879, COSV100916448; called by muse, mutect2, varscan2
- EPHB1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1330628001, COSV67671236; called by muse, mutect2, varscan2
- EPHB2 | c.1908C>A p.C636* (on ENST00000400191 / NM_001309193.2; = p.C637* on NM_004442.7) | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101007067; called by muse, mutect2, varscan2
- FAM161A | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs184627338, COSV100281296; called by muse, mutect2, varscan2
- FBXL7 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100309871; called by muse, mutect2
- FKBP10 | c.243A>G p.S81= | Splice Region (SNP) | VAF 63/166 reads (38%) | catalogued as COSV100387883; called by muse, mutect2, varscan2
- FLG | c.2671A>C p.S891R | Missense Mutation (SNP) | VAF 74/498 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1476265194, COSV100910462, COSV64239905; called by muse, mutect2, varscan2
- FLRT2 | c.506A>C p.N169T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1355192950, COSV58138681; called by muse, mutect2
- FRMPD3 | c.2457G>A p.M819I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99346373; called by muse, mutect2, varscan2
- GSTA4 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100919850; called by muse, mutect2, varscan2
- GTDC1 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99600521; called by muse, mutect2, varscan2
- GUCY2C | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV99663673; called by muse, mutect2, varscan2
- HS3ST5 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.466); catalogued as COSV100450935; called by muse, mutect2, varscan2
- IGLON5 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as COSV99570711; called by muse, mutect2, varscan2
- IQCA1 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV99609572; called by muse, mutect2, varscan2
- KCNE2 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV99285752; called by muse, varscan2
- LAMA2 | c.6739G>T p.A2247S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV101370481; called by muse, mutect2, varscan2
- LIMD1 | c.1666T>C p.Y556H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56268056, COSV99836968; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99523676; called by muse, mutect2, varscan2
- LRP11 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs1165611000, COSV99497801; called by muse, mutect2, varscan2
- MARK1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100857264; called by muse, mutect2
- MCPH1 | c.2260A>G p.T754A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100765773; called by muse, mutect2, varscan2
- MSI1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57457787; called by muse, mutect2
- NBEA | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.282); catalogued as COSV100080547; called by muse, mutect2
- NCKAP5 | c.3409G>C p.A1137P | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100492284; called by muse, mutect2, varscan2
- NID1 | c.1294dup p.Q432Pfs*23 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs777270836; called by pindel, varscan2
- NME7 | c.1111_1113del p.F371del | In Frame Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs777210651; called by pindel, varscan2
- NPBWR1 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV100488217; called by muse, mutect2
- NPC1L1 | c.3534C>A p.D1178E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99211606; called by muse, mutect2, varscan2
- OR4C6 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs202011136; called by muse, varscan2
- OR4N2 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60050647; called by muse, mutect2, varscan2
- OR5T2 | c.361T>G p.L121V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV100506948; called by muse, mutect2, varscan2
- OXCT1 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV99542180; called by muse, mutect2, varscan2
- PCDHA11 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV56519324; called by muse, mutect2, varscan2
- PCDHGA6 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.433); catalogued as COSV99536412; called by muse, mutect2, varscan2
- PCDHGB6 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV99538924; called by muse, mutect2, varscan2
- PDE3A | c.1883A>G p.N628S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.164); catalogued as rs1386365979, COSV100762163; called by muse, mutect2, varscan2
- PDZRN3 | c.1226A>C p.E409A | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV55198403, COSV99729842; called by muse, mutect2
- PKHD1 | c.6601T>G p.L2201V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as COSV100583222; called by muse, mutect2, varscan2
- PNPLA8 | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV99993560; called by muse, mutect2, varscan2
- PRR5L | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100287068, COSV61121294; called by muse, mutect2, varscan2
- PRSS58 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 28/111 reads (25%) | catalogued as COSV73488807; called by muse, mutect2, varscan2
- PZP | c.4372T>A p.Y1458N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99737958; called by muse, varscan2
- RBCK1 | c.563C>T p.A188V (on ENST00000356286 / NM_031229.4; = p.A146V on NM_006462.6) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100675841; called by muse, mutect2, varscan2
- RCBTB1 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319532; called by muse, mutect2, varscan2
- RGS18 | c.373A>C p.S125R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV100817794; called by mutect2, varscan2
- RSPO4 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54082810; called by muse, mutect2, varscan2
- RXFP3 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV100347565; called by muse, mutect2, varscan2
- SDK1 | c.5951C>A p.A1984E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101269399, COSV67355098; called by muse, mutect2
- SEC24A | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as rs372634474; called by muse, mutect2, varscan2
- SIN3A | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100845157; called by muse, mutect2, varscan2
- SLIT1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs752908466, COSV99821467; called by muse, mutect2, varscan2
- SMARCA2 | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100571070; called by muse, mutect2, varscan2
- SNTG2 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as rs754051995, COSV100422801; called by muse, mutect2, varscan2
- SOBP | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs751979917, COSV100433171, COSV99072560; called by muse, mutect2, varscan2
- SPOCK1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99969152; called by muse, mutect2
- SV2B | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100370704; called by muse, mutect2, varscan2
- TCF12 | c.1036-1G>C p.X346_splice | Splice Site (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99977651; called by muse, mutect2, varscan2
- TMEM132D | c.3019A>C p.N1007H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV101242861; called by muse, mutect2
- TNR | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99689769; called by muse, mutect2
- TRPC5 | c.1609C>G p.Q537E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461078, COSV99463180; called by muse, mutect2, varscan2
- TTN | c.80147T>C p.V26716A (on ENST00000591111; = p.V19292A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/141 reads (28%) | PolyPhen benign (0.02); catalogued as COSV100614593; called by muse, mutect2, varscan2
- TTN | c.64076C>A p.P21359Q (on ENST00000591111; = p.P13935Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | PolyPhen probably damaging (0.984); catalogued as COSV100614599; called by muse, mutect2, varscan2
- TTN | c.44095G>C p.A14699P (on ENST00000591111; = p.A7275P on NM_003319.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV100614605; called by muse, varscan2
- VPS13B | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347218901, COSV100662116; called by muse, mutect2, varscan2
- ZBTB2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs376506691; called by muse, mutect2, varscan2
- ZNF829 | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101199634; called by muse, mutect2, varscan2
- ANK3 | c.8433dup p.Q2812Tfs*4 | Frame Shift Ins (INS) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- ASPM | c.4150dup p.I1384Nfs*8 | Frame Shift Ins (INS) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- CLPB | c.372dup p.H125Sfs*68 | Frame Shift Ins (INS) | VAF 17/153 reads (11%) | called by mutect2, pindel, varscan2
- SLC9A4 | c.67dup p.C23Lfs*3 | Frame Shift Ins (INS) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- TAOK1 | c.1055_1058del p.Q352Pfs*29 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by pindel, varscan2
- TBC1D3L | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRAV8-1 | c.124_144del p.C42_G48del | In Frame Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- TTC17 | c.1838del p.K613Sfs*20 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- VPS13A | c.6156del p.F2052Lfs*5 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- ABCB4 | c.3258C>T p.Y1086= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1435564748, CM108952, COSV55933830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT6L | c.240T>C p.N80= (on ENST00000504123 / NM_001286790.2; = p.N75= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99361877; called by muse, mutect2, varscan2
- DNAH5 | c.3150G>A p.Q1050= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs750508944, COSV99450194; called by muse, mutect2, varscan2
- DRD2 | c.69C>T p.N23= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs200831689, COSV100669688; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDEM3 | c.288T>C p.V96= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100545335; called by muse, mutect2, varscan2
- FBN3 | c.5610C>T p.C1870= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99561006; called by muse, mutect2
- FBP1 | c.381C>T p.I127= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs771750403, COSV64689707; called by muse, mutect2, varscan2
- GTF3C1 | c.5403G>A p.A1801= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs368203794; called by muse, mutect2, varscan2
- IL10RA | c.885G>A p.P295= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs201071622, COSV99923114; called by muse, mutect2, varscan2
- IQGAP2 | c.4140G>A p.T1380= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs142258030, COSV57173175; called by muse, mutect2, varscan2
- IRS4 | c.777C>T p.T259= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100929567; called by muse, mutect2, varscan2
- IRX3 | c.552C>A p.R184= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100315242, COSV100315294; called by muse, mutect2, varscan2
- ITPKB | c.1887C>T p.P629= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs1010275487, COSV99684498; called by muse, mutect2
- LRRC39 | c.768A>G p.K256= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100734465; called by muse, mutect2, varscan2
- MMP19 | c.1512C>G p.T504= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100491114; called by muse, mutect2, varscan2
- MVP | c.1917C>T p.D639= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs747731704, COSV62422561; called by muse, mutect2, varscan2
- NPR3 | c.408C>T p.C136= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as COSV99423021; called by muse, mutect2, varscan2
- PCDHGC3 | c.147C>T p.N49= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV52752890; called by muse, mutect2, varscan2
- POLD2 | c.972G>A p.T324= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs757435023, COSV99788808; called by muse, mutect2
- PRDM9 | c.1728G>A p.G576= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs573799326, COSV99690506; called by muse, mutect2, varscan2
- TM6SF2 | c.579C>A p.P193= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101231601; called by muse, mutect2
- UCP2 | c.384C>T p.A128= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV100135063; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1761C>T | RNA (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101181723; called by muse, mutect2
- MAPK1IP1L | c.-9G>T | 5'UTR (SNP) | VAF 19/125 reads (15%) | catalogued as COSV100216208; called by muse, mutect2, varscan2
- SH3TC1 | c.172+232C>T | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as rs573433068, COSV55291827; called by muse, mutect2
- TRPM1 | c.724+1040C>T | Intron (SNP) | VAF 21/130 reads (16%) | catalogued as rs780832965, COSV99855995; called by muse, mutect2, varscan2
- XIST | n.7263C>T | RNA (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
